Somatic mutation profile of tumor specimen TCGA-VS-A9U6-01A (aliquot TCGA-VS-A9U6-01A-11D-A42O-09) from TCGA case TCGA-VS-A9U6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: GX; Age at diagnosis: 52.3 years (19,109 days).
Specimen TCGA-VS-A9U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d567b59e-fe93-4d80-be4b-c21902c9238c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9U6-10A (Blood Derived Normal), aliquot TCGA-VS-A9U6-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4b74ec4-43b6-4444-b7b7-bcba7f7f265d

The open-access MAF lists 513 somatic variants for this specimen: 376 protein-altering or splice-affecting, 129 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 129, Frame Shift Del 56, Nonsense Mutation 25, Frame Shift Ins 17, In Frame Del 5, Splice Site 5, Splice Region 4, 5'Flank 3, Intron 2, In Frame Ins 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs397516135, HM0650, COSV62519421; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.842dup p.L282Afs*3 | Frame Shift Ins (INS) | VAF 19/55 reads (35%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- AASS | c.767-1G>A p.X256_splice | Splice Site (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100741666; called by muse, mutect2, varscan2
- ABCB10 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100747852; called by muse, mutect2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs749943218; called by mutect2, varscan2
- ABHD8 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56044094; called by muse, mutect2, varscan2
- ACAD9 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs781520431, COSV100458961; called by muse, mutect2, varscan2
- AGPAT4 | c.907dup p.R303Pfs*60 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | catalogued as rs750826126; called by mutect2, varscan2
- AMER3 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV100365961; called by mutect2, varscan2
- ANK3 | c.2632G>A p.G878R (on ENST00000280772 / NM_001320874.2; = p.G12R on NM_001149.3) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770736443, COSV55062433; called by muse, mutect2, varscan2
- ANKRD23 | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as COSV100450324; called by muse, mutect2, varscan2
- ARHGAP20 | c.2774C>A p.P925Q | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99503103; called by muse, mutect2
- ARL1 | c.509T>C p.M170T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99880271; called by muse, mutect2, varscan2
- ATG13 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV100365468, COSV100365497, COSV56318903; called by muse, mutect2, varscan2
- ATP13A3 | c.3079T>G p.W1027G | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as rs1336026013; called by mutect2, varscan2
- ATP13A4 | c.3079dup p.M1027Nfs*4 | Frame Shift Ins (INS) | VAF 15/141 reads (11%) | catalogued as rs754612408; called by mutect2, pindel, varscan2
- ATP2A2 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100428393; called by muse, mutect2, varscan2
- ATP7B | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV99666042; called by muse, mutect2, varscan2
- AXIN2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1343964499, COSV100195912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAS3 | c.2158G>A p.E720K (on ENST00000390652 / NM_001353144.2; = p.E705K on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV101175207; called by muse, mutect2, varscan2
- BICRA | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV101194230; called by muse, mutect2, varscan2
- BIRC6 | c.12952G>T p.E4318* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as COSV101427849; called by muse, mutect2, varscan2
- BNC1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100597116, COSV61757588; called by muse, mutect2, varscan2
- BTBD11 | c.3181G>A p.E1061K (on ENST00000280758 / NM_001018072.2; = p.E598K on NM_001017523.2) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as rs897076308, COSV55023919; called by muse, mutect2, varscan2
- BTN2A2 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100760235; called by muse, mutect2, varscan2
- C3 | c.1437G>A p.M479I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99836069; called by muse, mutect2, varscan2
- CALD1 | c.2092G>A p.A698T (on ENST00000361675 / NM_033138.4; = p.A443T on NM_004342.7) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV100724020; called by muse, mutect2, varscan2
- CALN1 | c.197G>A p.R66H (on ENST00000329008 / NM_001017440.3; = p.R108H on NM_031468.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762029880, COSV100204904; called by muse, mutect2, varscan2
- CBLB | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as COSV99912676; called by muse, mutect2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CCDC105 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757213881, COSV52965891; called by muse, mutect2, varscan2
- CCDC191 | c.2178G>T p.K726N | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV99877912; called by muse, mutect2, varscan2
- CCDC85A | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.916); catalogued as rs752612593, COSV101339379, COSV68150243; called by muse, mutect2, varscan2
- CCNT2 | c.774+2T>C p.X258_splice | Splice Site (SNP) | VAF 40/137 reads (29%) | catalogued as COSV99750138; called by muse, mutect2
- CCR10 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs1282202709, COSV99226120; called by muse, mutect2, varscan2
- CCT5 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs998269335, COSV54724191; called by muse, mutect2, varscan2
- CD22 | c.986-1G>A p.X329_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99322854; called by muse, mutect2, varscan2
- CD7 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.766); catalogued as COSV99486114; called by muse, mutect2, varscan2
- CDC42BPB | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1250404274, COSV100775191; called by muse, mutect2, varscan2
- CDH12 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV101201416, COSV66394638; called by muse, mutect2, varscan2
- CDH23 | c.8167G>A p.V2723M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99818879; called by muse, mutect2, varscan2
- CEACAM3 | c.12del p.S5Qfs*21 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | catalogued as COSV55761330, COSV55763508; called by mutect2, pindel, varscan2
- CEP126 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99680574; called by muse, mutect2
- CERS2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs774392793, COSV99643783; called by muse, mutect2, varscan2
- CFAP44 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99868907; called by muse, mutect2, varscan2
- CFAP52 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as rs1328613291, COSV100234771; called by muse, mutect2
- CFAP91 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as COSV99846814; called by muse, mutect2, varscan2
- CHD2 | c.3454C>T p.R1152W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101244719; called by muse, mutect2, varscan2
- CHD3 | c.3362G>A p.R1121Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57875552; called by muse, mutect2, varscan2
- CHST15 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs368746217, COSV60566097; called by muse, mutect2, varscan2
- CHSY1 | c.666dup p.P223Afs*29 | Frame Shift Ins (INS) | VAF 21/50 reads (42%) | catalogued as rs762321510; called by mutect2, varscan2
- CIART | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); catalogued as rs1553854665, COSV99290060; called by muse, mutect2, varscan2
- CKM | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as rs1343248816, COSV99675445; called by muse, mutect2, varscan2
- CLCA4 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99760204, COSV99760826; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSPN | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99230295; called by muse, mutect2
- CLSTN3 | c.2633C>G p.S878* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99866537; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A2 | c.5063G>A p.G1688D (on ENST00000341947 / NM_080680.3; = p.G1581D on NM_080679.2) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59494657; called by muse, varscan2
- COL4A6 | c.4699C>T p.R1567C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563364; called by muse, mutect2, varscan2
- COPG1 | c.841A>T p.S281C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100135360; called by muse, mutect2, varscan2
- CPNE2 | c.99G>C p.Q33H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.699); catalogued as COSV99321216; called by muse, mutect2, varscan2
- CRELD1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV99925520; called by muse, mutect2, varscan2
- CRMP1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100271347; called by muse, mutect2, varscan2
- CRY2 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs1308494289, COSV101314555; called by muse, mutect2, varscan2
- CYP21A2 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.658); catalogued as COSV100925831, COSV100926202; called by mutect2, varscan2
- CYP21A2 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as COSV100925832; called by muse, varscan2
- DBF4 | c.1223del p.K408Sfs*16 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs749089320; called by mutect2, pindel, varscan2
- DCAF8 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1205424160, COSV100470166; called by muse, mutect2, varscan2
- DENND5B | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60909199; called by muse, mutect2, varscan2
- DIAPH1 | c.2139G>A p.M713I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1356765386, COSV99525828; called by muse, mutect2, varscan2
- DIAPH1 | c.1751C>A p.P584H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV99525830; called by muse, mutect2, varscan2
- DLX3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1032099378, COSV71547429; called by muse, mutect2, varscan2
- DMWD | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755365606, COSV52180145; called by muse, mutect2, varscan2
- DNA2 | c.2407C>G p.L803V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as COSV100622365; called by muse, mutect2, varscan2
- DNAH17 | c.13166G>C p.G4389A | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99427984; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH7 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.64); catalogued as rs756273227, COSV100413839, COSV56770735; called by muse, mutect2, varscan2
- DNAJB14 | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100508257; called by muse, mutect2, varscan2
- DNAJC5B | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52535695, COSV99395865; called by muse, mutect2, varscan2
- DOCK5 | c.5321T>A p.L1774Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99376046; called by muse, mutect2, varscan2
- DOK3 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100466831; called by muse, mutect2, varscan2
- DPP8 | c.1202G>A p.R401H (on ENST00000341861 / NM_001320875.2; = p.R385H on NM_017743.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs147974541, COSV55683291; called by muse, mutect2, varscan2
- DPYSL4 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs777898676, COSV100061816; called by muse, mutect2, varscan2
- DYNC1H1 | c.13423G>A p.V4475I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV100794431; called by muse, mutect2, varscan2
- ECI1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100066486; called by muse, mutect2, varscan2
- EFCAB12 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs181124030, COSV100394474; called by muse, varscan2
- EGR4 | c.1732G>A p.G578S (on ENST00000545030; = p.G475S on NM_001965.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1053349350, COSV71531965; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs748937918; called by mutect2, varscan2
- ENAH | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99490080; called by muse, mutect2, varscan2
- EPAS1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99762908; called by muse, mutect2, varscan2
- ERCC6L2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99998270; called by muse, mutect2, varscan2
- FAM177A1 | c.199G>A p.E67K (on ENST00000382406 / NM_001289022.2; = p.E90K on NM_173607.5) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99805679; called by muse, mutect2, varscan2
- FAM200A | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs1157185419, COSV101282701; called by muse, mutect2, varscan2
- FAM47C | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.284); catalogued as rs151225998, COSV100792277; called by muse, mutect2, varscan2
- FARS2 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99212901; called by muse, mutect2, varscan2
- FBLN2 | c.3401G>T p.R1134M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99851416; called by muse, mutect2, varscan2
- FDPS | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs1273852227, COSV100756081, COSV63115267; called by muse, mutect2, varscan2
- FEM1C | c.1401G>C p.Q467H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV57232050, COSV99174346; called by muse, mutect2, varscan2
- FGF21 | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99711367; called by muse, mutect2, varscan2
- FMO3 | c.392G>T p.R131M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV100882395; called by muse, mutect2, varscan2
- FOXM1 | c.710C>A p.P237Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700796; called by muse, mutect2, varscan2
- FREM2 | c.3952G>A p.D1318N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV54829428, COSV99746847; called by muse, mutect2, varscan2
- FRMD4B | c.2530C>A p.H844N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.321); catalogued as COSV101273332; called by muse, mutect2, varscan2
- GALNT14 | c.915G>T p.W305C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61112823; called by muse, mutect2, varscan2
- GALNT6 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149784974; called by muse, mutect2, varscan2
- GANAB | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100647825; called by muse, mutect2, varscan2
- GANAB | c.699C>G p.H233Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV100647826; called by muse, mutect2, varscan2
- GATB | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858711; called by muse, mutect2, varscan2
- GCNA | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs773686081, COSV101032389; called by muse, varscan2
- GCNT4 | c.880del p.H294Ifs*14 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs768450027; called by pindel, varscan2
- GGA1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100289638; called by muse, mutect2, varscan2
- GGN | c.1667T>A p.V556E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV99287312; called by muse, mutect2, varscan2
- GGT5 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs989337416, COSV99571263; called by muse, mutect2
- GHR | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV100049887; called by muse, mutect2, varscan2
- GLO1 | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297233225, COSV100974066; called by muse, mutect2, varscan2
- GOLGA5 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV50833913; called by muse, mutect2, varscan2
- GOT2 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99803432; called by muse, mutect2, varscan2
- GPATCH1 | c.1777del p.D593Ifs*6 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as COSV50116689; called by mutect2, pindel, varscan2
- GPX2 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV100767397; called by muse, mutect2, varscan2
- GRIA1 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV99598150; called by muse, mutect2, varscan2
- GRIN3A | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.048); catalogued as COSV100701367, COSV62451415; called by muse, mutect2, varscan2
- GRM4 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303810855, COSV100945738; called by muse, mutect2, varscan2
- GRM4 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.616); catalogued as rs770014744, COSV65219038; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2786C>T p.A929V (on ENST00000265755 / NM_016328.3; = p.A914V on NM_005685.4) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99734048; called by muse, mutect2, varscan2
- GYG2 | c.1022C>A p.P341Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100088690, COSV58551241; called by muse, mutect2, varscan2
- H2AC8 | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as COSV99773037; called by muse, mutect2, varscan2
- HECW2 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771657143, COSV53671601; called by muse, mutect2, varscan2
- HIPK4 | c.1140del p.T381Rfs*52 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs768093416; called by mutect2, pindel, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 4/42 reads (10%) | catalogued as rs759915055; called by pindel, varscan2
- HNRNPF | c.162T>A p.S54R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100562961; called by muse, mutect2, varscan2
- HOXB3 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV57486733, COSV57487505; called by muse, mutect2, varscan2
- HSPA13 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV53466057, COSV53466084; called by muse, mutect2, varscan2
- ING5 | c.478G>T p.G160* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100545911; called by muse, varscan2
- INTS11 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as rs1366887266, COSV100028005, COSV100028786, COSV60090775; called by muse, mutect2, varscan2
- IP6K3 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99539577; called by muse, mutect2
- IQSEC1 | c.1709G>A p.S570N | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99831310; called by muse, mutect2
- IQSEC2 | c.2842G>A p.V948M (on ENST00000642864 / NM_001111125.3; = p.V743M on NM_015075.2) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV100944739; called by muse, mutect2, varscan2
- IRF7 | c.646dup p.A216Gfs*199 (on ENST00000397566; = p.A203Gfs*199 on NM_001572.5) | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | catalogued as rs746222183; called by mutect2, pindel, varscan2
- ITGB4 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs753166262, COSV99563385; called by muse, mutect2, varscan2
- KALRN | c.8600G>T p.G2867V (on ENST00000360013 / NM_001024660.4; = p.G1170V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99361061; called by muse, mutect2, varscan2
- KCNJ13 | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99289215; called by muse, mutect2, varscan2
- KDM4A | c.2961+2T>C p.X987_splice | Splice Site (SNP) | VAF 19/111 reads (17%) | catalogued as COSV99494929; called by muse, mutect2, varscan2
- KHDRBS3 | c.58_60del p.F20del | In Frame Del (DEL) | VAF 66/159 reads (42%) | catalogued as rs1280573530; called by mutect2, pindel, varscan2
- KIAA1109 | c.11149C>T p.R3717* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as rs527467559, COSV99145826; called by muse, mutect2, varscan2
- KIAA2026 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67354284; called by muse, mutect2, varscan2
- KIF13A | c.1986G>C p.Q662H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as COSV99433887; called by muse, varscan2
- KIF17 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs766378781, COSV99928524; called by muse, mutect2, varscan2
- KIFC2 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs754906340, COSV100023479; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 26/111 reads (23%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRT19 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV99562882; called by muse, mutect2, varscan2
- LAMA5 | c.7359G>A p.E2453= | Splice Region (SNP) | VAF 30/69 reads (43%) | catalogued as COSV99438074; called by muse, mutect2, varscan2
- LIG1 | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs764106045, COSV99618500; called by muse, varscan2
- LIPH | c.1142G>T p.R381I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV99955785; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP1 | c.5174G>A p.S1725N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99674453; called by muse, mutect2, varscan2
- LRRC41 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100586107; called by muse, mutect2
- LRRC49 | c.101dup p.N34Kfs*4 | Frame Shift Ins (INS) | VAF 28/110 reads (25%) | catalogued as rs769868170; called by mutect2, varscan2
- LRRIQ1 | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101279514; called by muse, mutect2, varscan2
- MAN2B1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375598352; called by muse, mutect2, varscan2
- MAP3K13 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53993300, COSV99406449; called by muse, mutect2, varscan2
- MAPK8IP3 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99167665; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3326C>A p.S1109Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51599709, COSV99167668; called by muse, mutect2, varscan2
- MC1R | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as rs768902395, COSV100205599; called by muse, varscan2
- MED23 | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100644763; called by muse, mutect2, varscan2
- MESP2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as COSV100510688; called by muse, mutect2, varscan2
- MIB1 | c.2141A>G p.Q714R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.6); catalogued as COSV99838359; called by muse, mutect2, varscan2
- MIER1 | c.1000G>A p.E334K (on ENST00000355356 / NM_001077701.3; = p.E351K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100590823; called by muse, varscan2
- MMP11 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1325899869, COSV99303059; called by muse, mutect2, varscan2
- MORC3 | c.2187G>C p.Q729H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV101264843; called by muse, mutect2, varscan2
- MRNIP | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as rs116981436, COSV52972176; called by muse, mutect2, varscan2
- MTF1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs1371060530, COSV100888572; called by muse, mutect2, varscan2
- MUC16 | c.24902del p.N8301Tfs*5 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs1444756959; called by mutect2, pindel, varscan2
- MUC5B | c.6593A>G p.H2198R | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as COSV101500034; called by muse, mutect2, varscan2
- MYH7 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs869130333, COSV100805698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO10 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV101549833; called by muse, mutect2
- MYO1B | c.2216G>T p.R739M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100268639; called by muse, mutect2, varscan2
- MYO1C | c.3116C>G p.P1039R (on ENST00000648651 / NM_001080779.2; = p.P1004R on NM_033375.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100704234; called by muse, mutect2, varscan2
- NBAS | c.6890C>T p.A2297V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99867228; called by muse, mutect2, varscan2
- NCOR2 | c.3969_3971del p.S1324del | In Frame Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs1228463283; called by pindel, varscan2
- NDEL1 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs200450931, COSV100232735; called by muse, mutect2, varscan2
- NEDD4 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV101436577; called by muse, mutect2, varscan2
- NFATC4 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99144350; called by muse, varscan2
- NPHP3 | c.3875_3877del p.E1292del | In Frame Del (DEL) | VAF 12/115 reads (10%) | catalogued as rs1200012206; called by pindel, varscan2
- NRN1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as COSV99783967; called by muse, mutect2, varscan2
- NRROS | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100145353, COSV60746985; called by muse, mutect2
- NUP153 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs556345430, COSV100019832; called by muse, mutect2, varscan2
- NUP153 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs773370651, COSV50450642; called by muse, mutect2, varscan2
- NUP205 | c.5685T>C p.F1895= | Splice Region (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99606453; called by muse, mutect2, varscan2
- OBSCN | c.11051G>A p.R3684H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.086); catalogued as rs571833899, COSV52800150; called by muse, mutect2, varscan2
- OPTC | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs747920513, COSV100921729; called by muse, mutect2, varscan2
- OR8B8 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); catalogued as COSV100044819; called by muse, mutect2, varscan2
- ORC5 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV99856714; called by muse, mutect2, varscan2
- OTOF | c.5954C>A p.S1985Y (on ENST00000272371 / NM_194248.3; = p.S1218Y on NM_004802.4) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99716535; called by muse, mutect2
- OTOF | c.4130C>T p.A1377V (on ENST00000272371 / NM_194248.3; = p.A610V on NM_004802.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99716537; called by muse, mutect2
- P3H4 | c.1077C>A p.Y359* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100821207; called by muse, mutect2, varscan2
- PABPC5 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1446595654, COSV57038971, COSV57039392; called by muse, mutect2, varscan2
- PAK5 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.423); catalogued as COSV100781105; called by muse, mutect2, varscan2
- PAPPA2 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100866543; called by muse, mutect2
- PAXBP1 | c.2132C>T p.T711I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99269025; called by muse, mutect2, varscan2
- PCDHA9 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs782219075, COSV65329183; called by muse, mutect2, varscan2
- PCDHGA2 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as rs369706288; called by muse, mutect2, varscan2
- PCDHGB3 | c.2146C>T p.R716* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs1208837944, COSV53894285; called by muse, mutect2
- PCNT | c.5188C>T p.R1730* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as rs755987047, COSV100855051; called by muse, mutect2, varscan2
- PDCD2 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV51341279; called by muse, mutect2, varscan2
- PDE3A | c.1388G>A p.S463N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.33); catalogued as rs1386177820, COSV100761676; called by muse, mutect2, varscan2
- PEG10 | c.159G>T p.E53D (on ENST00000482108 / NM_001040152.2; = p.E87D on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.017); catalogued as COSV101509848; called by muse, mutect2
- PENK | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100152164; called by muse, mutect2, varscan2
- PER1 | c.2329G>T p.G777W | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100424259; called by muse, mutect2, varscan2
- PHF12 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.15); catalogued as rs764314067, COSV99255460; called by muse, mutect2, varscan2
- PHLDB2 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV101208397; called by muse, mutect2, varscan2
- PHTF1 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs911931113, COSV100760001; called by muse, mutect2, varscan2
- PIK3R4 | c.2717C>T p.S906L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100768205; called by muse, mutect2, varscan2
- PIP5K1A | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.01); catalogued as COSV100576510; called by muse, mutect2, varscan2
- PKD1L1 | c.6473G>T p.R2158M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV99218457; called by muse, mutect2, varscan2
- PKIG | c.93G>T p.E31D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.13); catalogued as COSV100596070; called by muse, mutect2, varscan2
- PKM | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100064483; called by muse, mutect2, varscan2
- PLA2G15 | c.230T>G p.L77R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99547074; called by muse, mutect2, varscan2
- PLA2R1 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.183); catalogued as rs1272376706, COSV99322171; called by muse, mutect2, varscan2
- PLD2 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs386352350, COSV99562033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.2138G>A p.R713Q (on ENST00000322810 / NM_201380.4; = p.R603Q on NM_000445.5) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs199826059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG5 | c.2950G>T p.G984W (on ENST00000400915 / NM_001042663.3; = p.G947W on NM_020631.6) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV100556098, COSV61068038; called by muse, varscan2
- PML | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99166677; called by muse, mutect2, varscan2
- PNN | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as rs1027389637, COSV99397046; called by muse, mutect2, varscan2
- POR | c.1897G>T p.G633W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100115477; called by muse, mutect2, varscan2
- PPP1R42 | c.453G>T p.L151F | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61209053; called by muse, mutect2, varscan2
- PRIM1 | c.663del p.K221Nfs*24 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs1194932333; called by mutect2, pindel, varscan2
- PRR5 | c.433C>T p.R145C (on ENST00000336985 / NM_181333.4; = p.R136C on NM_015366.4) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752935264, COSV50064904; called by muse, mutect2, varscan2
- PRRC2A | c.4838G>A p.R1613H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs760310035, COSV52989670; called by muse, mutect2, varscan2
- PSME4 | c.2328A>C p.E776D | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV101122227; called by muse, mutect2, varscan2
- PTCD1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138833009; called by muse, mutect2, varscan2
- PXDNL | c.1813G>C p.A605P | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100681449; called by muse, mutect2
- PXDNL | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1473307923, COSV62496619; called by muse, mutect2, varscan2
- RAB11FIP2 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100842990; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1264T>C p.W422R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424424; called by muse, mutect2, varscan2
- RAD54L | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs780047827, COSV100586105; called by muse, mutect2, varscan2
- RAI14 | c.816dup p.R273Tfs*15 | Frame Shift Ins (INS) | VAF 26/84 reads (31%) | catalogued as rs1355946206; called by mutect2, varscan2
- RASA2 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | catalogued as rs756541842, COSV99655621; called by muse, mutect2, varscan2
- RASAL1 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs1341664111, COSV99921426; called by muse, mutect2, varscan2
- RASGRF2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs376856331; called by muse, mutect2, varscan2
- RB1 | c.1727C>G p.S576* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as CD040611, COSV57295141, COSV57300560; called by muse, mutect2, varscan2
- RBM25 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.885); catalogued as rs1343993607, COSV56198346; called by mutect2, varscan2
- RBP1 | c.118_121del p.D40Kfs*10 (on ENST00000619087 / NM_001365940.2; = p.D102Kfs*10 on NM_002899.5) | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | catalogued as rs878859724; called by mutect2, pindel, varscan2
- RIN3 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs776608506, COSV53654225; called by muse, mutect2, varscan2
- RING1 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100761720; called by muse, mutect2, varscan2
- RLN3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1451118330; called by muse, mutect2, varscan2
- RNF126 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as COSV99293628; called by muse, varscan2
- RNF148 | c.699G>C p.K233N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100411429, COSV57386946; called by muse, mutect2, varscan2
- RNF213 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as rs376901868; called by mutect2, varscan2
- RNF220 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 77/110 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100131784; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RSAD1 | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99364116; called by muse, mutect2, varscan2
- RSRC1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.656); catalogued as rs773344897, COSV99905422; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | catalogued as rs759252078; called by mutect2, varscan2
- RUBCN | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754358548, COSV56364971; called by muse, mutect2, varscan2
- RUFY2 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100700058; called by muse, mutect2, varscan2
- SAMD11 | c.133_135del p.K45del | In Frame Del (DEL) | VAF 27/195 reads (14%) | catalogued as rs1181839556; called by pindel, varscan2
- SAP30BP | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99502679; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs763290832; called by mutect2, varscan2
- SCN11A | c.3048G>C p.E1016D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100180974; called by muse, mutect2, varscan2
- SCYL2 | c.1031G>C p.R344T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV100675042; called by muse, mutect2, varscan2
- SECISBP2L | c.1413del p.K471Nfs*20 (on ENST00000559471 / NM_001193489.2; = p.K426Nfs*20 on NM_014701.4) | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs768725524; called by mutect2, varscan2
- SENP6 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.241); catalogued as COSV100894306; called by muse, mutect2, varscan2
- SETX | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs748148688, COSV56385881; called by muse, mutect2, varscan2
- SH3RF1 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756340632, COSV52920358, COSV99498650; called by muse, varscan2
- SLC16A5 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100316960; called by muse, mutect2, varscan2
- SLC1A5 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV101314751; called by muse, mutect2, varscan2
- SLC22A7 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101000760; called by muse, mutect2, varscan2
- SLC23A1 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100811867; called by muse, mutect2, varscan2
- SLC25A22 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs775147140, COSV100204096; called by muse, mutect2, varscan2
- SLC26A3 | c.1341C>A p.N447K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384823; called by muse, mutect2, varscan2
- SLC2A7 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs755498344, COSV101280745; called by muse, mutect2, varscan2
- SLC33A1 | c.1475C>G p.A492G | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100848243; called by muse, mutect2
- SLC38A11 | c.506G>T p.G169V (on ENST00000409149 / NM_001351539.1; = p.G147V on NM_173512.2) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100366722; called by muse, mutect2, varscan2
- SLC4A2 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1435964008, COSV100054852; called by muse, mutect2
- SLC5A9 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs756014240, COSV52582778; called by muse, mutect2, varscan2
- SLFN12 | c.555dup p.D186* | Frame Shift Ins (INS) | VAF 27/67 reads (40%) | catalogued as rs747319777; called by mutect2, varscan2
- SLFN13 | c.1185_1187del p.Q395del | In Frame Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs771967762; called by pindel, varscan2
- SLK | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100211481; called by muse, mutect2
- SOCS6 | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV101205645; called by muse, mutect2, varscan2
- SORBS3 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99530936; called by muse, mutect2, varscan2
- SPATA22 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99279112; called by muse, mutect2, varscan2
- SPATA31E1 | c.2888C>T p.T963I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV100349930; called by muse, mutect2, varscan2
- SPEG | c.5528C>A p.P1843H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100403276; called by muse, mutect2, varscan2
- SPTBN5 | c.1148G>T p.R383M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100310657; called by muse, mutect2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs1470980144, COSV72486131; called by mutect2, pindel, varscan2
- SRRM2 | c.2825C>T p.T942M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs762679915, COSV100070192; called by muse, mutect2, varscan2
- STAT5B | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752593400, COSV53182781; called by muse, mutect2, varscan2
- STOX2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV57857982; called by muse, mutect2, varscan2
- STYXL2 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1178648571, COSV99608589; called by muse, mutect2, varscan2
- SYT14 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV99654555; called by muse, mutect2, varscan2
- SYT3 | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100143867; called by muse, mutect2, varscan2
- TACR3 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs780364097, COSV59200695; called by muse, mutect2
- TAL1 | c.872G>A p.C291Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99595877; called by muse, mutect2, varscan2
- TCHH | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs780690938, COSV64275322; called by muse, mutect2
- TCHP | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100452506; called by muse, mutect2, varscan2
- TEX55 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs769025284, COSV55211411, COSV99817295; called by muse, mutect2, varscan2
- TFAP4 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99200026; called by muse, mutect2, varscan2
- THBS2 | c.2072G>A p.C691Y | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100827599; called by muse, mutect2, varscan2
- TICRR | c.5524A>G p.S1842G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1442031904, COSV99176014; called by muse, mutect2, varscan2
- TIGD3 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99361338; called by muse, mutect2, varscan2
- TIMM21 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553191760, COSV99399993; called by muse, mutect2, varscan2
- TMEM132A | c.2017G>A p.A673T (on ENST00000453848 / NM_178031.3; = p.A674T on NM_017870.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as rs765110880, COSV99133958; called by muse, mutect2, varscan2
- TMEM61 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as COSV100987724; called by muse, mutect2, varscan2
- TNFRSF25 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs144966576; called by muse, mutect2, varscan2
- TNKS2 | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771829801, COSV65416650; called by muse, mutect2, varscan2
- TNNT3 | c.295_297dup p.E99dup (on ENST00000397301 / NM_001367846.1; = p.E88dup on NM_006757.4) | In Frame Ins (INS) | VAF 5/28 reads (18%) | catalogued as rs764019640; called by mutect2, varscan2
- TNXB | c.11576C>A p.S3859* (on ENST00000647633; = p.S3612* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as COSV100925839; called by muse, varscan2
- TNXB | c.8944G>A p.E2982K (on ENST00000647633; = p.E2735K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.897); catalogued as COSV100925842; called by muse, mutect2, varscan2
- TOM1L1 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100779135; called by muse, mutect2, varscan2
- TPST2 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100113964; called by muse, mutect2
- TRAM1L1 | c.394del p.S132Lfs*9 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs757906221; called by mutect2, pindel, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as rs780358338; called by mutect2, varscan2
- TRNAU1AP | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.488); catalogued as rs752773020, COSV100867825, COSV65778358; called by muse, mutect2, varscan2
- TRPS1 | c.2768A>G p.Y923C (on ENST00000220888 / NM_001330599.2; = p.Y936C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99628464; called by muse, mutect2, varscan2
- TTC7B | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV60629811; called by muse, mutect2, varscan2
- TXNRD1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as rs769989720, COSV71220598; called by muse, mutect2, varscan2
- UGT3A2 | c.1053G>A p.W351* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as rs1407421241, COSV99235991; called by muse, mutect2, varscan2
- USP24 | c.4352G>A p.R1451H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370480612; called by muse, mutect2, varscan2
- VPS13B | c.2026T>G p.F676V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100660879; called by muse, mutect2, varscan2
- WNT7B | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100254753; called by muse, mutect2, varscan2
- WT1 | c.493T>G p.F165V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as COSV100186967; called by muse, mutect2, varscan2
- WWC3 | c.277A>T p.I93L | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV101081048; called by muse, mutect2, varscan2
- XIRP1 | c.3402del p.W1135Gfs*2 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs1166941994; called by mutect2, pindel, varscan2
- XRCC6 | c.774-2A>G p.X258_splice | Splice Site (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100777778; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF14 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV100693972; called by muse, mutect2, varscan2
- ZNF354C | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100203480; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF404 | c.1450C>G p.Q484E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.297); catalogued as COSV100182303; called by muse, mutect2
- ZNF689 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54910331; called by muse, mutect2, varscan2
- ZSCAN9 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV99356312; called by muse, mutect2, varscan2
- ZSWIM3 | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as rs1330481147, COSV99666123; called by muse, mutect2, varscan2
- ZSWIM8 | c.3626C>T p.A1209V (on ENST00000605216 / NM_001242487.2; = p.A1214V on NM_015037.3) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs770884227, COSV100013630; called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | called by mutect2, pindel, varscan2
- ABCA6 | c.763del p.M255* | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- AP4M1 | c.566del p.L189Wfs*10 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.2319dup p.L774Tfs*5 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- CACNA1H | c.6158del p.G2053Afs*135 | Frame Shift Del (DEL) | VAF 24/119 reads (20%) | called by mutect2, pindel, varscan2
- CDC42EP4 | c.873del p.S292Afs*90 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- CERS4 | c.109dup p.Q37Pfs*21 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- CHD8 | c.3119del p.N1040Tfs*12 (on ENST00000646647 / NM_001170629.2; = p.N761Tfs*12 on NM_020920.4) | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- CLDN6 | c.567del p.S190Pfs*70 | Frame Shift Del (DEL) | VAF 21/110 reads (19%) | called by mutect2, pindel, varscan2
- COL7A1 | c.4322dup p.G1442Wfs*8 | Frame Shift Ins (INS) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- DST | c.19093dup p.T6365Nfs*23 (on ENST00000361203 / NM_001374722.1; = p.T4062Nfs*23 on NM_015548.5) | Frame Shift Ins (INS) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- FOXK1 | c.1224del p.F409Sfs*18 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- FREM2 | c.5906_5909del p.S1969Cfs*12 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- IL16 | c.351del p.K117Nfs*2 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- ING5 | c.412dup p.R138Kfs*26 | Frame Shift Ins (INS) | VAF 13/73 reads (18%) | called by pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, varscan2
- KMT2D | c.7593del p.S2532Lfs*11 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- LRP1 | c.10966dup p.L3656Pfs*23 | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- LTBP2 | c.5446del p.H1816Tfs*32 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by pindel, varscan2*
- MDGA1 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- NIPBL | c.4269dup p.V1424Cfs*6 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- PHTF2 | c.1709dup p.L570Ffs*10 (on ENST00000248550 / NM_001366089.1; = p.L532Ffs*10 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | called by mutect2, varscan2
- PIK3R4 | c.1794del p.F598Lfs*4 | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | called by mutect2, pindel, varscan2
- POT1 | c.703-3del | Splice Region (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- RAD51AP2 | c.946del p.T316Lfs*2 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- RGS21 | c.455del p.L152Cfs*7 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- RXRG | c.1318_1320dup p.F440dup | In Frame Ins (INS) | VAF 22/120 reads (18%) | called by mutect2, varscan2
- SAMD9 | c.153del p.E52Nfs*16 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- SASS6 | c.567del p.K189Nfs*4 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, varscan2
- SH3PXD2B | c.147del p.F49Lfs*47 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- SLC27A5 | c.1809del p.G604Afs*40 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- SLC9A4 | c.1447del p.T483Pfs*15 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- SYNJ1 | c.1210del p.Y404Ifs*35 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- TCERG1 | c.3148dup p.I1050Nfs*5 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- USP32 | c.2726del p.L909Cfs*13 | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | called by mutect2, pindel, varscan2
- WIZ | c.2620del p.L874Wfs*13 (on ENST00000673675 / NM_001371589.1; = p.L137Wfs*13 on NM_021241.3) | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- WWC2 | c.2730del p.E911Rfs*16 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- ZFC3H1 | c.3429del p.F1143Lfs*9 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- ZNF160 | c.410del p.N137Mfs*36 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- ADAM28 | c.456G>A p.E152= | Silent (SNP) | VAF 40/56 reads (71%) | catalogued as rs1051633381, COSV99737776; called by muse, mutect2, varscan2
- ADCY8 | c.369C>T p.G123= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99650777; called by muse, mutect2, varscan2
- ADGRG6 | c.1785T>C p.T595= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99745833; called by muse, mutect2, varscan2
- ADRM1 | c.495C>T p.H165= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV99438070; called by muse, mutect2, varscan2
- ADTRP | c.630T>C p.L210= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV99995037; called by muse, mutect2, varscan2
- AMPD2 | c.261T>C p.R87= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV99857348; called by muse, mutect2, varscan2
- APCDD1 | c.1026C>T p.Y342= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs186987345; called by muse, mutect2, varscan2
- APOL1 | c.891G>A p.P297= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs148496792; called by muse, mutect2, varscan2
- ARSF | c.753C>T p.H251= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as rs142421943, COSV100839430; called by muse, mutect2, varscan2
- ASB8 | c.582G>C p.L194= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100402270; called by muse, varscan2
- ASPA | c.867C>T p.Y289= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as rs375736464; called by muse, mutect2, varscan2
- B3GALT5 | c.513G>C p.L171= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100563284; called by muse, mutect2, varscan2
- BIRC6 | c.8418G>A p.Q2806= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV101427848; called by muse, mutect2, varscan2
- BRSK1 | c.837T>C p.I279= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100473660; called by muse, mutect2, varscan2
- C1QTNF4 | c.969C>G p.L323= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100209199; called by muse, mutect2, varscan2
- CACHD1 | c.921A>G p.S307= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99261459; called by muse, mutect2, varscan2
- CACNA1I | c.5718C>T p.F1906= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs762849541, COSV100359237; called by muse, mutect2, varscan2
- CCDC18 | c.1053C>T p.D351= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs200869845, COSV58144091; called by muse, mutect2, varscan2
- CCT2 | c.18T>C p.L6= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1320497230, COSV100167506; called by muse, mutect2, varscan2
- CD1A | c.522A>T p.I174= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV99192181; called by muse, mutect2, varscan2
- CD46 | c.516A>G p.K172= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100522755; called by muse, mutect2, varscan2
- CD79B | c.48G>A p.A16= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs758062682, COSV99137599; called by muse, varscan2
- CFAP43 | c.804C>T p.Y268= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99530379; called by muse, mutect2, varscan2
- CLCA4 | c.906C>A p.I302= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV99760206; called by muse, mutect2, varscan2
- COL16A1 | c.4221A>G p.G1407= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs943729707, COSV99593571; called by muse, mutect2, varscan2
- COL26A1 | c.612G>T p.P204= (on ENST00000313669 / NM_001278563.3; = p.P202= on NM_133457.4) | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as COSV100561478; called by muse, mutect2, varscan2
- DHX15 | c.189T>G p.A63= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100391140; called by muse, varscan2
- DNA2 | c.1797T>C p.R599= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100622367; called by muse, mutect2, varscan2
- DNAH10 | c.4398G>A p.T1466= (on ENST00000409039; = p.T1405= on NM_207437.3) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs557510209, COSV101291976; called by muse, mutect2, varscan2
- DNM3 | c.831G>A p.L277= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100797771; called by muse, mutect2, varscan2
- DRP2 | c.2826C>A p.P942= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV101235124; called by muse, mutect2, varscan2
- DST | c.2544G>A p.Q848= (on ENST00000361203 / NM_001374722.1; = p.Q522= on NM_001723.6) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99751166; called by muse, mutect2, varscan2
- EIF3F | c.210G>A p.A70= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs775110839, COSV100562480; called by muse, varscan2
- EIF4G2 | c.2529C>T p.F843= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100379359; called by muse, mutect2, varscan2
- EPHA10 | c.12C>T p.C4= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV60406283; called by muse, mutect2
- EPHB6 | c.294C>T p.R98= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs773799287, COSV101235943; called by muse, mutect2, varscan2
- ERBB3 | c.1422T>C p.L474= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99915795; called by muse, mutect2, varscan2
- FBN1 | c.5379T>C p.C1793= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as CM040042, COSV100354029; called by muse, mutect2, varscan2
- FBXL16 | c.306C>T p.L102= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs893498250, COSV100178724; called by muse, mutect2, varscan2
- FBXO10 | c.711C>T p.N237= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs371415820; called by muse, mutect2, varscan2
- FCGBP | c.6924T>C p.P2308= | Silent (SNP) | VAF 49/308 reads (16%) | called by muse, mutect2, varscan2
- FITM1 | c.243C>A p.A81= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99246017; called by muse, mutect2, varscan2
- GANAB | c.1536C>T p.F512= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100647824; called by muse, mutect2, varscan2
- GCC1 | c.1863T>C p.P621= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100365388; called by muse, mutect2
- GPR20 | c.513C>T p.C171= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs370586508, COSV100897263; called by muse, mutect2, varscan2
- HERC2 | c.3975G>A p.P1325= | Silent (SNP) | VAF 69/187 reads (37%) | catalogued as rs759567478, COSV55319796, COSV55328782; called by muse, mutect2, varscan2
- HGD | c.660C>T p.G220= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99380644; called by muse, mutect2, varscan2
- HSPA4 | c.1857C>T p.N619= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs142002805; called by muse, mutect2, varscan2
- HYDIN | c.13665C>T p.G4555= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs1383846464, COSV66638918; called by muse, mutect2, varscan2
- IQCC | c.198C>T p.S66= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs866045381, COSV99356313; called by muse, mutect2, varscan2
- IRS1 | c.552C>T p.R184= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs144915638; called by muse, mutect2, varscan2
- ITGB4 | c.4479C>T p.N1493= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99563387; called by muse, mutect2, varscan2
- ITIH5 | c.582C>T p.S194= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV56910799; called by muse, varscan2
- KCNG3 | c.711C>T p.I237= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs750630963, COSV60150172; called by muse, mutect2, varscan2
- KCNJ12 | c.1044C>A p.T348= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100054027; called by muse, mutect2, varscan2
- KCNMB2 | c.267G>A p.A89= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs754356731, COSV100844016, COSV64200769; called by muse, mutect2, varscan2
- KRT34 | c.1080C>T p.I360= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs755328052, COSV101222549; called by muse, mutect2, varscan2
- LNX1 | c.903C>T p.I301= (on ENST00000263925 / NM_001126328.3; = p.I205= on NM_032622.2) | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV55782727; called by muse, mutect2, varscan2
- LRP1 | c.1143C>G p.V381= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99674451; called by muse, mutect2, varscan2
- LRRC6 | c.381C>A p.S127= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99137736; called by muse, mutect2, varscan2
- LRRTM1 | c.732G>A p.K244= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99701818; called by muse, mutect2
- MAGEB6 | c.18G>A p.K6= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100983655; called by muse, mutect2, varscan2
- MAPKAPK2 | c.246C>T p.F82= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV99685742; called by muse, mutect2, varscan2
- MPRIP | c.1074C>T p.D358= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as rs764009264, COSV59045781; called by muse, mutect2, varscan2
- MYH7 | c.2592G>A p.E864= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100805699; called by muse, mutect2, varscan2
- MYOF | c.4500G>A p.T1500= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs763946104, COSV63712993; called by muse, mutect2, varscan2
- NDST2 | c.1230C>A p.L410= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100013631, COSV55213542; called by muse, mutect2, varscan2
- NLGN4X | c.411C>A p.T137= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as COSV99319921; called by muse, mutect2, varscan2
- NRXN3 | c.513C>T p.G171= (on ENST00000557594 / NM_001272020.2; = p.G803= on NM_004796.6) | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV99815936; called by muse, mutect2, varscan2
- NUP210 | c.4827C>T p.I1609= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs777191665, COSV99595577; called by muse, mutect2, varscan2
- NXF1 | c.234A>G p.R78= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99585750; called by muse, mutect2, varscan2
- OR1M1 | c.594C>T p.F198= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101447539; called by muse, mutect2, varscan2
- OSBP2 | c.448C>T p.L150= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs747699976, COSV100212646; called by muse, mutect2, varscan2
- OTOF | c.3831C>T p.I1277= (on ENST00000272371 / NM_194248.3; = p.I510= on NM_004802.4) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99716540; called by muse, mutect2, varscan2
- OTX1 | c.234G>A p.P78= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1032645182, COSV56996426; called by muse, mutect2, varscan2
- PALM | c.843C>T p.G281= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs199542927, COSV52768364; called by muse, mutect2, varscan2
- PAPOLB | c.357C>T p.C119= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV101271481, COSV68201187; called by muse, mutect2, varscan2
- PCDH10 | c.2520C>T p.C840= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99992978; called by muse, mutect2, varscan2
- PCDHAC1 | c.771C>A p.A257= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV53874494, COSV99165032; called by muse, mutect2, varscan2
- PCDHGB4 | c.243C>T p.S81= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs760517049; called by muse, mutect2, varscan2
- PDE4DIP | c.3342T>C p.N1114= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100516504; called by muse, mutect2, varscan2
- PHC3 | c.486T>C p.T162= (on ENST00000494943 / NM_001308116.2; = p.T174= on NM_024947.4) | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100767229; called by muse, mutect2, varscan2
- PIK3CG | c.666C>T p.I222= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs772212264, COSV63246035; called by muse, mutect2
- PIPOX | c.777G>A p.L259= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100037846; called by muse, mutect2, varscan2
- PLA2G7 | c.36C>G p.L12= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs35142331, COSV51268404; called by muse, mutect2, varscan2
- PM20D1 | c.741C>T p.L247= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs372016896; called by muse, varscan2
- PNPLA1 | c.408A>T p.S136= (on ENST00000394571 / NM_001374623.1; = p.S41= on NM_173676.2) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100462650, COSV57236719; called by muse, mutect2, varscan2
- PTGFR | c.474T>C p.G158= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100882239; called by muse, mutect2, varscan2
- PTPN20 | c.1251G>C p.L417= | Silent (SNP) | VAF 126/447 reads (28%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.312C>T p.D104= (on ENST00000401957 / NM_001367602.2; = p.D407= on NM_012294.5) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100686496; called by mutect2, varscan2
- REST | c.1899C>A p.P633= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100470678; called by muse, mutect2, varscan2
- RFNG | c.348G>T p.A116= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV100135847; called by muse, mutect2
- RPL7L1 | c.78G>A p.L26= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV59035144; called by muse, mutect2, varscan2
- RRS1 | c.624C>T p.H208= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs954370183, COSV99397581; called by muse, mutect2, varscan2
- SART3 | c.1389G>A p.L463= (on ENST00000228284; = p.L445= on NM_014706.4) | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99933847; called by muse, mutect2, varscan2
- SEPTIN9 | c.375C>T p.I125= (on ENST00000427177 / NM_001113491.2; = p.I107= on NM_006640.4) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs573465338, COSV61203709; called by muse, mutect2, varscan2
- SLC16A3 | c.1020C>T p.F340= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs373465497, COSV58363772, COSV58366249; called by muse, mutect2, varscan2
- SLC6A6 | c.1578G>A p.K526= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV100691895; called by muse, mutect2, varscan2
- SMARCA4 | c.4848G>A p.P1616= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs370590601, COSV100758149; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNAP47 | c.1254G>A p.L418= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100247921; called by muse, mutect2, varscan2
- SNPH | c.177G>A p.T59= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs770060374, COSV101118524; called by muse, mutect2, varscan2
- SNX32 | c.1027C>T p.L343= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100362560; called by muse, mutect2, varscan2
- SNX8 | c.1107G>T p.V369= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99770532; called by muse, mutect2
- SPATA22 | c.630G>A p.K210= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99279109; called by muse, mutect2, varscan2
- SPEG | c.8574G>A p.A2858= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs1414519807, COSV100403278; called by muse, mutect2, varscan2
- SSH1 | c.2955C>T p.L985= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs776967409, COSV100425334; called by muse, mutect2, varscan2
- SYNJ2 | c.639C>T p.R213= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100840018; called by muse, mutect2, varscan2
- TAF3 | c.2565C>T p.Y855= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs756305633, COSV100719823; called by muse, mutect2, varscan2
- TAOK1 | c.291T>C p.R97= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV99913527; called by muse, mutect2, varscan2
- TBL1X | c.820T>C p.L274= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99482097; called by muse, mutect2, varscan2
- THBS3 | c.190C>T p.L64= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100366737; called by muse, mutect2, varscan2
- TMEM132D | c.867C>T p.S289= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1437970397, COSV101396482; called by muse, mutect2, varscan2
- TMEM147 | c.321C>A p.A107= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99382130; called by muse, mutect2, varscan2
- TMEM38A | c.166C>T p.L56= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV51818284; called by muse, mutect2, varscan2
- TMEM44 | c.793C>A p.R265= (on ENST00000392432 / NM_001166305.2; = p.R218= on NM_138399.5) | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as rs547220835, COSV99861535, COSV99861801; called by muse, mutect2, varscan2
- TMOD2 | c.432C>T p.L144= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV99987614; called by muse, mutect2, varscan2
- TMPRSS9 | c.957C>T p.N319= (on ENST00000648592; = p.N285= on NM_182973.2) | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as rs368841376; called by muse, mutect2, varscan2
- TNRC6C | c.2160C>T p.R720= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100049469; called by muse, mutect2, varscan2
- TNXB | c.11649C>G p.L3883= (on ENST00000647633; = p.L3636= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs1191083407, COSV100925836; called by muse, varscan2
- TP53BP2 | c.2520T>C p.P840= (on ENST00000343537 / NM_001031685.3; = p.P711= on NM_005426.2) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100636505; called by muse, mutect2, varscan2
- TRHDE | c.2208T>C p.N736= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99669145; called by muse, mutect2, varscan2
- TSC22D2 | c.2325G>A p.P775= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs749890286, COSV100721186; called by muse, mutect2, varscan2
- TTC39C | c.382C>A p.R128= (on ENST00000317571 / NM_001135993.2; = p.R67= on NM_153211.4) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100455151, COSV58221724; called by muse, mutect2, varscan2
- VTN | c.663C>T p.L221= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99879468; called by muse, mutect2, varscan2
- VWA2 | c.183C>T p.S61= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs754260936, COSV100073305; called by muse, mutect2, varscan2
- XPC | c.933C>T p.L311= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99542071; called by muse, mutect2, varscan2
- ZFP1 | c.957G>A p.T319= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs775977714, COSV100181960; called by muse, mutect2, varscan2
- ZNF710 | c.1707C>T p.H569= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs761488485, COSV99184081; called by muse, mutect2, varscan2
- ZP3 | c.1206G>A p.L402= (on ENST00000394857 / NM_001110354.2; = p.L351= on NM_007155.6) | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100334447; called by mutect2, varscan2
- AL132655.6 | chr20:58840832 C>T | 5'Flank (SNP) | VAF 11/37 reads (30%) | catalogued as rs1228262845, COSV100005312; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849068 G>T | 5'Flank (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- ATP8B2 | c.1133+85G>C | Intron (SNP) | VAF 19/41 reads (46%) | catalogued as COSV59245388; called by muse, mutect2, varscan2
- BCAP29 | chr7:107621764 del C | 3'Flank (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- FOLH1B | n.1079G>T | RNA (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- GOLIM4 | c.*1C>T | 3'UTR (SNP) | VAF 19/76 reads (25%) | catalogued as rs373039345; called by muse, mutect2, varscan2
- PRR12 | chr19:49594458 C>T | 5'Flank (SNP) | VAF 21/81 reads (26%) | catalogued as rs1281138564, COSV99882291; called by muse, mutect2, varscan2
- TRIM61 | c.526-2183G>A | Intron (SNP) | VAF 14/33 reads (42%) | catalogued as rs1437910088, COSV61418725; called by muse, mutect2, varscan2
